Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7483, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7483-01A (Primary Tumor).

Pathology Report

Microscopic Discussion:

Sections demonstrate a moderately hypercellular glial neoplasm, the cells of which primarily resemble fibrillary astrocytes. A small but definite oligodendroglioma component is also seen. The tumor diffusely infiltrates gray and white matter. No microvascular proliferation or necrosis are present. No mitotic figures are seen. Atypia is generally mild. Scattered moderately atypical cells are present.

.

Addendum Discussion:

Scattered MIB-1 reactive cells are present. In the most proliferative areas, a labeling index of 6.1% is calculated. This is indicative of an intermediate level of proliferation and a level that can be seen in either low or anaplastic tumors. The overall histologic features are indicative of a low grade tumor. However, close follow up is indicated.

Final Addendum Diagnosis:

Oligoastrocytoma, astrocytoma predominant, low grade (WHO grade II)

Source: NCI Genomic Data Commons file 99a76602-4428-4b3d-b62d-516510c5a1b3 (TCGA-HT-7483.A5C5D547-2D3D-41DF-A490-76350DC7E7C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).